Somatic mutation profile of tumor specimen TCGA-EL-A3GY-01A (aliquot TCGA-EL-A3GY-01A-21D-A202-08) from TCGA case TCGA-EL-A3GY, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 40.6 years (14,814 days).
Specimen TCGA-EL-A3GY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 938b6c3c-3658-4533-b715-070efec22667.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3GY-10A (Blood Derived Normal), aliquot TCGA-EL-A3GY-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a276ad41-a038-4e83-aabe-746aa1c52bde

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BTN2A1 | c.819A>T p.Q273H | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV57004474; called by muse, mutect2
- CYP11A1 | c.8C>G p.A3G | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.115); catalogued as COSV51433063; called by muse, mutect2, varscan2
- ITGB1 | c.581C>G p.P194R | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56483550; called by muse, mutect2
- LRRC42 | c.644A>T p.D215V | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV59961201; called by muse, mutect2, varscan2
- NRXN3 | c.427A>T p.I143L (on ENST00000557594 / NM_001272020.2; = p.I775L on NM_004796.6) | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as COSV55336910; called by muse, mutect2, varscan2
- PCDHGA5 | c.1418C>G p.S473C | Missense Mutation (SNP) | VAF 16/327 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.288); catalogued as COSV53979099; called by muse, mutect2
- TM2D3 | c.716G>A p.G239E (on ENST00000333202 / NM_078474.3; = p.G213E on NM_025141.3) | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60881439; called by muse, mutect2
- TG | c.5707_5708dup p.C1904Sfs*7 | Frame Shift Ins (INS) | VAF 6/59 reads (10%) | called by mutect2, pindel, varscan2
- AGO2 | c.2094C>T p.Y698= | Silent (SNP) | VAF 11/127 reads (9%) | catalogued as rs761378470, COSV55049222; called by muse, mutect2
